CCDI case PBCDSK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/68d58ed3-b144-4fd4-beb8-227685879a5d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 7.1 years (2,592 days).

Biospecimens (3 samples)
- Sample 0DPJSA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPJSL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPJT6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
